CCDI case PBBSPF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/eee8c79e-c51f-433b-bc80-3be57955e3f3

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.4 years (878 days).

Biospecimens (2 samples)
- Sample 0DFXF1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFXGX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
